Somatic mutation profile of tumor specimen TCGA-QK-A8Z7-01A (aliquot TCGA-QK-A8Z7-01A-11D-A391-08) from TCGA case TCGA-QK-A8Z7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 59.4 years (21,711 days).
Specimen TCGA-QK-A8Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6115cee9-5aeb-4fc0-aef4-9ecaff2a7010.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A8Z7-10A (Blood Derived Normal), aliquot TCGA-QK-A8Z7-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aaa4292-a000-446b-ba93-c89a33c50969

The open-access MAF lists 154 somatic variants for this specimen: 124 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 29, Nonsense Mutation 12, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADORA2A | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs4990; called by muse, mutect2, varscan2
- AGGF1 | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100462117; called by muse, mutect2, varscan2
- AGPS | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99931584; called by muse, mutect2
- ANO3 | c.1456T>A p.F486I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99884568; called by muse, mutect2, varscan2
- ASXL3 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99325907; called by muse, mutect2, varscan2
- C1orf159 | c.452G>T p.G151V (on ENST00000379339 / NM_001330306.2; = p.G115V on NM_017891.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99618738; called by muse, mutect2, varscan2
- CAPN12 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100185448; called by muse, mutect2
- CCDC114 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100196941; called by muse, mutect2, varscan2
- CCDC142 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99282297; called by muse, mutect2, varscan2
- CCDC40 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs61736668, COSV53896744; called by muse, mutect2, varscan2
- CCDC50 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV100484320; called by muse, mutect2, varscan2
- CDH19 | c.1604G>T p.R535I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1245492312, COSV50954545; called by muse, mutect2
- CDKN2D | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51565672, COSV99140950; called by muse, mutect2
- CHERP | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.043); catalogued as COSV99550419; called by muse, mutect2, varscan2
- CLTC | c.2262C>A p.Y754* | Nonsense Mutation (SNP) | VAF 47/132 reads (36%) | catalogued as COSV99292679; called by muse, mutect2, varscan2
- CMTR1 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 106/159 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100990902; called by muse, mutect2, varscan2
- CNOT2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV99972916; called by muse, mutect2, varscan2
- COG6 | c.1827-1G>C p.X609_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100743176; called by muse, mutect2
- COL14A1 | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920119; called by muse, mutect2, varscan2
- COL9A3 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99416047; called by muse, mutect2, varscan2
- CPXM2 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV99582883; called by muse, mutect2, varscan2
- CRB1 | c.849-1G>A p.X283_splice | Splice Site (SNP) | VAF 9/147 reads (6%) | catalogued as rs1481592460, COSV100959172, COSV66347542; called by muse, mutect2
- CROT | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs201693830, COSV100519503, COSV100519628; called by muse, mutect2, varscan2
- CTNND2 | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100479547; called by muse, mutect2, varscan2
- DYRK1B | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs753051620, COSV100546695; called by muse, mutect2
- DZIP3 | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV100847958; called by muse, mutect2, varscan2
- EHMT1 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 51/186 reads (27%) | catalogued as COSV101509720; called by muse, mutect2, varscan2
- EIF3A | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100974720; called by muse, mutect2, varscan2
- EML3 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 76/121 reads (63%) | catalogued as COSV99606038; called by muse, mutect2, varscan2
- FAM120A | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99465965; called by muse, mutect2, varscan2
- FGA | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV100120580; called by muse, mutect2, varscan2
- FGF1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (1); PolyPhen probably damaging (0.927); catalogued as rs764725960, COSV100532451; called by muse, mutect2, varscan2
- FIGN | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100292728; called by muse, mutect2
- FSCN1 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV100435250, COSV61018956; called by muse, mutect2
- GFOD1 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); catalogued as rs753393250, COSV64954627; called by muse, mutect2, varscan2
- GJA10 | c.1421C>G p.T474S | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV101005415; called by muse, mutect2, varscan2
- GOLGB1 | c.3343A>G p.I1115V | Missense Mutation (SNP) | VAF 113/234 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100511320; called by muse, mutect2, varscan2
- H2AC13 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 117/201 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs768930206, COSV100704420, COSV100704432; called by muse, mutect2, varscan2
- H3-3B | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV54665480; called by muse, mutect2, varscan2
- HDAC4 | c.3178G>T p.A1060S | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100612916, COSV100613976; called by muse, mutect2, varscan2
- HTATSF1 | c.2026T>A p.S676T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV54481160, COSV99511823; called by muse, mutect2
- IBSP | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99883702; called by muse, mutect2, varscan2
- IGSF9B | c.3658G>A p.A1220T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100318173; called by muse, mutect2, varscan2
- IL17RA | c.186G>T p.W62C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083363; called by muse, mutect2, varscan2
- JMJD1C | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101232449, COSV67863931; called by muse, mutect2, varscan2
- JUP | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV100159724; called by muse, mutect2, varscan2
- KCNF1 | c.918C>G p.H306Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99705818; called by muse, mutect2, varscan2
- KLC3 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101228911; called by muse, mutect2, varscan2
- KRT71 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99922326; called by muse, mutect2, varscan2
- KRTAP10-10 | c.728T>G p.L243R | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); catalogued as COSV100554841; called by muse, mutect2, varscan2
- LAMC2 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99917735; called by muse, mutect2
- LOXL2 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV101207958; called by muse, mutect2, varscan2
- LRP1B | c.2771-1G>T p.X924_splice | Splice Site (SNP) | VAF 22/34 reads (65%) | catalogued as COSV101259042, COSV67203483; called by muse, mutect2, varscan2
- LRRC55 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV101546758; called by muse, mutect2, varscan2
- MAPT | c.23T>C p.F8S | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99291055; called by muse, mutect2, varscan2
- MARCHF11 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100198147, COSV60127746; called by muse, mutect2, varscan2
- MASP1 | c.436A>T p.R146W | Missense Mutation (SNP) | VAF 151/213 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99397523; called by muse, mutect2, varscan2
- MTIF2 | c.1897T>A p.S633T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99703244; called by muse, mutect2, varscan2
- MUC16 | c.32528dup p.H10844Pfs*2 | Frame Shift Ins (INS) | VAF 60/222 reads (27%) | catalogued as rs745530053; called by mutect2, varscan2
- MUC16 | c.26800C>A p.L8934I | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.006); catalogued as rs1220325168, COSV101199872; called by muse, mutect2, varscan2
- MUC17 | c.8885C>A p.S2962Y | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV100074448; called by muse, mutect2, varscan2
- MYO3A | c.2725G>T p.G909* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99780855; called by muse, mutect2, varscan2
- MYRF | c.1045C>T p.Q349* (on ENST00000278836 / NM_001127392.3; = p.Q340* on NM_013279.4) | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | catalogued as COSV53892748, COSV99607552; called by muse, mutect2, varscan2
- NAAA | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as rs561108824, COSV99716037; called by muse, mutect2
- NCAM1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100377614; called by muse, mutect2, varscan2
- NEK5 | c.1276-1G>A p.X426_splice | Splice Site (SNP) | VAF 61/113 reads (54%) | catalogued as COSV100839275; called by muse, mutect2, varscan2
- NLRC3 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100073135; called by muse, mutect2, varscan2
- NLRP10 | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149864; called by muse, mutect2, varscan2
- NLRP2 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV99672515; called by muse, mutect2, varscan2
- NOTCH1 | c.5680G>A p.G1894S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs1334842062, COSV53063141; called by muse, mutect2, varscan2
- NRXN2 | c.1703A>T p.D568V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99635237; called by muse, mutect2, varscan2
- NUMA1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as COSV61188355; called by muse, mutect2, varscan2
- OLFM2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778983446, COSV99321942; called by muse, mutect2
- OLFM3 | c.641T>G p.M214R (on ENST00000338858 / NM_001288821.1; = p.M194R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.88); catalogued as COSV100129882; called by muse, mutect2, varscan2
- OR8K3 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as COSV57132057; called by muse, mutect2, varscan2
- PCDH8 | c.2279G>T p.C760F | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100131936; called by muse, mutect2
- PDE3A | c.2905G>T p.V969F | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100762634; called by muse, mutect2
- PON2 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99749875; called by muse, mutect2
- POU4F1 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV101020581; called by muse, mutect2
- PPM1D | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as rs372024236, COSV99045417; called by muse, mutect2, varscan2
- PRF1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942659; called by muse, mutect2, varscan2
- PRLR | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99184620; called by muse, mutect2, varscan2
- PRUNE2 | c.4717C>T p.Q1573* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100944954; called by muse, mutect2, varscan2
- PSMD13 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 54/268 reads (20%) | catalogued as COSV100728880; called by muse, mutect2, varscan2
- PTPRE | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV99618559; called by muse, mutect2, varscan2
- PUM1 | c.2863C>G p.R955G | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99928656; called by muse, mutect2, varscan2
- RFXAP | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99715212; called by muse, mutect2, varscan2
- RNF130 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99992880; called by muse, mutect2, varscan2
- RNF148 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as COSV100411683; called by muse, mutect2, varscan2
- SEL1L2 | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99533659; called by muse, mutect2, varscan2
- SKA3 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.191); catalogued as COSV100006458; called by muse, mutect2, varscan2
- SLC2A6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376983675, COSV52470059; called by muse, mutect2, varscan2
- SLC38A10 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 55/92 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs768323092, COSV99917738; called by muse, mutect2, varscan2
- SPINK4 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV101121903; called by muse, mutect2, varscan2
- SRP68 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 200/749 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.228); catalogued as COSV57162928; called by muse, mutect2, varscan2
- SRRM4 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV57413189, COSV99939052; called by muse, mutect2, varscan2
- STS | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99481538; called by muse, mutect2, varscan2
- SVEP1 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs765955604, COSV57029599; called by muse, mutect2, varscan2
- SYT12 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101210968; called by muse, mutect2, varscan2
- SYT7 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs382505, COSV55654064, COSV55659794; called by muse, mutect2, varscan2
- TDRD6 | c.1751G>C p.R584T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749874371, COSV100288050; called by muse, mutect2, varscan2
- TET3 | c.3203C>A p.A1068D | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101328011; called by muse, mutect2, varscan2
- TIAM2 | c.4960C>G p.P1654A (on ENST00000529824; = p.P1625A on NM_012454.3) | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.491); catalogued as rs201653955, COSV99265828; called by muse, mutect2, varscan2
- TMEM107 | c.281C>T p.S94F (on ENST00000437139 / NM_183065.4; = p.S100F on NM_032354.5) | Missense Mutation (SNP) | VAF 114/157 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1408799401, COSV100328799; called by muse, mutect2, varscan2
- TMEM132E | c.1077del p.I360Sfs*7 (on ENST00000321639; = p.I450Sfs*7 on NM_001304438.2) | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV58696831; called by mutect2, pindel, varscan2
- TMPRSS6 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100696048; called by muse, mutect2, varscan2
- TOMM40L | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1365294517, COSV100915815; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TTN | c.30611C>T p.A10204V (on ENST00000591111; = p.A9277V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/15 reads (93%) | PolyPhen benign (0.12); catalogued as COSV100615430; called by muse, mutect2, varscan2
- TXK | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765225089, COSV99972688; called by muse, mutect2, varscan2
- UACA | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 145/276 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537637; called by muse, mutect2, varscan2
- ZFP1 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200868124, COSV100182131; called by muse, mutect2
- ZFYVE1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs1411060748, COSV59612903; called by muse, mutect2, varscan2
- ZNF254 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100298257; called by muse, mutect2, varscan2
- ZNF479 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 11/155 reads (7%) | catalogued as COSV100482425, COSV100482933; called by muse, mutect2, varscan2
- CDH9 | c.1759_1760del p.R587Cfs*6 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- GDF10 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HNRNPL | c.1218dup p.G407Wfs*22 | Frame Shift Ins (INS) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.44A>T p.K15I | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PKD1L2 | c.920_923del p.N307Rfs*24 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- POLR2A | c.5234G>A p.S1745N | Missense Mutation (SNP) | VAF 158/225 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- WDR53 | c.1074_1075del p.F358Lfs*? | Frame Shift Del (DEL) | VAF 20/198 reads (10%) | called by mutect2, pindel
- WDR55 | c.1134_1135del p.D380* | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- XPO4 | c.971_972dup p.E325Lfs*5 | Frame Shift Ins (INS) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- ACTR1B | c.978C>T p.I326= | Silent (SNP) | VAF 108/271 reads (40%) | catalogued as COSV100008161; called by muse, mutect2, varscan2
- ARFGEF3 | c.5220C>T p.P1740= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV99294283; called by muse, mutect2, varscan2
- ATP10A | c.927C>T p.D309= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs141485196; called by muse, mutect2, varscan2
- C1orf159 | c.453C>T p.G151= (on ENST00000379339 / NM_001330306.2; = p.G115= on NM_017891.5) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99618729; called by muse, mutect2, varscan2
- CACNA1H | c.2208C>T p.H736= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs376616017; called by muse, mutect2, varscan2
- EIF3A | c.2583G>A p.R861= | Silent (SNP) | VAF 86/251 reads (34%) | catalogued as rs891409623, COSV100974717; called by muse, mutect2, varscan2
- EMSY | c.2865C>T p.S955= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV100595908; called by muse, mutect2, varscan2
- EXOC6B | c.1146C>A p.I382= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99725711; called by muse, mutect2, varscan2
- FCGBP | c.252C>T p.P84= | Silent (SNP) | VAF 80/177 reads (45%) | catalogued as rs368985940; called by muse, mutect2, varscan2
- IGSF3 | c.2976C>T p.S992= (on ENST00000369486 / NM_001007237.3; = p.S1012= on NM_001542.4) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1242331012, COSV100604979; called by muse, varscan2
- KALRN | c.1878C>T p.I626= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs779697643, COSV99566353; called by muse, mutect2, varscan2
- KASH5 | c.483C>T p.D161= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV101483483; called by muse, mutect2, varscan2
- LRG1 | c.393G>T p.L131= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV100015022; called by muse, mutect2, varscan2
- LRRN3 | c.501T>A p.L167= | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as COSV100072392; called by muse, mutect2, varscan2
- MOCOS | c.1482G>A p.G494= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs1003227226, COSV99733723; ClinVar: likely benign; called by muse, mutect2
- MRM2 | c.438G>A p.R146= | Silent (SNP) | VAF 63/122 reads (52%) | catalogued as COSV99642749; called by muse, mutect2, varscan2
- PCDH10 | c.1062C>T p.N354= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as COSV52095951; called by muse, mutect2, varscan2
- PCDHGA8 | c.1722C>T p.G574= | Silent (SNP) | VAF 129/194 reads (66%) | catalogued as COSV53913414; called by muse, mutect2, varscan2
- PCLO | c.5169C>T p.S1723= | Silent (SNP) | VAF 52/91 reads (57%) | catalogued as COSV100435544; called by muse, mutect2, varscan2
- PPP1R26 | c.591C>A p.G197= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100778125; called by muse, mutect2
- PSG4 | c.657A>T p.I219= | Silent (SNP) | VAF 36/277 reads (13%) | catalogued as COSV99737536; called by muse, mutect2, varscan2
- RPUSD4 | c.111C>T p.A37= | Silent (SNP) | VAF 140/296 reads (47%) | catalogued as COSV100028832; called by muse, mutect2, varscan2
- RXFP3 | c.177C>T p.G59= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV100347713; called by muse, mutect2, varscan2
- SLC12A7 | c.630G>T p.T210= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV99369861, COSV99370338; called by muse, mutect2, varscan2
- SMC2 | c.1452G>A p.Q484= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV99659440; called by muse, mutect2
- SYNPO2 | c.1542A>T p.V514= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100206171; called by muse, mutect2, varscan2
- TASOR2 | c.3421T>C p.L1141= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV100050791; called by muse, mutect2, varscan2
- TRIM42 | c.1761C>T p.S587= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as rs1475931529, COSV99648655; called by muse, mutect2, varscan2
- VPS18 | c.852C>T p.F284= | Silent (SNP) | VAF 44/169 reads (26%) | catalogued as rs775470341, COSV99592616; called by muse, mutect2, varscan2
- TTN | c.10360+4098T>C | Intron (SNP) | VAF 53/68 reads (78%) | catalogued as rs397517809, COSV100623172; ClinVar: likely benign; called by muse, mutect2, varscan2
